Gene-level copy-number profile of tumor specimen TCGA-13-0768-01A from TCGA case TCGA-13-0768, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 73.9 years (26,999 days).
Specimen TCGA-13-0768-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.c26c83eb-091f-4940-ae98-62e16254cc05.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0768-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/90057a9f-6c74-4cc2-94c3-acbeaf211f4a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,163; copy number 2: 32,750; copy number 3: 10,548; copy number 4: 1,233; copy number 5: 1,414; copy number 6: 47; copy number 7: 216; copy number 8: 57; copy number 9: 62; copy number 11: 180; copy number 13: 47; copy number 14: 12; copy number 15: 18; copy number 23: 14; copy number 36: 3; copy number 39: 48; copy number 45: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0768-01A-01D-0356-01): tumor purity 0.21, ploidy 2.37, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,025 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:27,725,961–28,193,936, 23 genes, copy number 5 (within-gene range 3–5): FAM76A, AL020997.1, RPEP3, STX12, AL020997.2, AL020997.3, RNU6-1245P, AL020997.4, PPP1R8, SCARNA1, THEMIS2, RPA2, SMPDL3B, AL512288.1, XKR8, EYA3, AL512288.2, RN7SL559P, SPCS2P4, AL137792.2, AL137792.1, RNU6-176P, PTAFR.
- chr2:112,275,597–118,835,110, 101 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:108,032,456–108,589,644, 11 genes, copy number 7: AC012020.1, CD47, LINC01215, IFT57, HHLA2, HNRNPA1P17, MYH15, AC069499.1, CIP2A, SNORA70, AC069499.2.
- chr5:218,298–1,523,962, 48 genes, copy number 39 (within-gene range 1–39): AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075.
- chr5:1,708,785–1,728,172, 2 genes, copy number 45: MIR4277, AC112176.1.
- chr5:37,377,049–41,510,628, 61 genes, copy number 13–23 (within-gene range 2–23) (broad region; genes not listed).
- chr7:63,011,463–100,336,307, 741 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:132,570,416–145,066,685, 278 genes, copy number 5 (broad region; genes not listed).
- chr9:23,500,691–24,088,051, 10 genes, copy number 5: AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1.
- chr10:83,067,962–83,314,475, 2 genes, copy number 5: RNU6-478P, MARK2P15.
- chr14:23,767,662–35,932,325, 229 genes, copy number 5 (broad region; genes not listed).
- chr14:35,947,556–35,950,044, 1 gene, copy number 5: AL133304.1.
- chr18:1,883,524–2,655,395, 12 genes, copy number 14: AP005230.1, AIDAP3, AP005136.4, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2.
- chr19:14,732,392–16,660,442, 115 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr19:27,638,483–38,426,305, 370 genes, copy number 6–11 (broad region; genes not listed).
- chr22:39,743,044–39,893,864, 1 gene, copy number 15 (within-gene range 2–15): ENTHD1.
- chr22:39,874,255–40,682,814, 20 genes, copy number 15–36: RN7SKP210, UQCRFS1P1, GRAP2, Z82206.1, FAM83F, Z83847.1, TNRC6B, RPL7P52, ADSL, AL022238.3, SGSM3, SGSM3-AS1, MRTFA, AL022238.2, AL022238.1, MRTFA-AS1, COX6B1P3, RPL4P6, GAPDHP37, MCHR1.

Autosomal genes at a single copy (total copy number 1): 11,114. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
